Gene-level copy-number profile of tumor specimen TCGA-78-7163-01A from TCGA case TCGA-78-7163, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.2 years (22,002 days).
Specimen TCGA-78-7163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4561c40e-e736-4f4c-b18a-62c43e149e07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7163-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e0a7dfb-6b6c-4e2d-bbd2-d5cc209587a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 2,763; copy number 3: 472; copy number 4: 33,538; copy number 5: 1,853; copy number 6: 11,685; copy number 8: 4,470; copy number 9: 4,980; copy number 10: 43; copy number 11: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7163-01A-12D-2062-01): tumor purity 0.68, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,989 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–16,432,702, 253 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr2:29,060,976–42,332,548, 186 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:50,829,442–55,112,621, 48 genes, copy number 9 (within-gene range 6–9): AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P.
- chr7:38,257,879–38,318,861, 9 genes, copy number 10: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr11:167,784–135,075,908, 3,355 genes, copy number 9 (broad region; genes not listed).
- chr16:46,469,341–70,801,160, 629 genes, copy number 9 (broad region; genes not listed).
- chr16:70,852,698–70,852,814, 1 gene, copy number 9: RNU6ATAC25P.
- chr16:71,281,389–90,222,851, 508 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
